Surgical pathology report (de-identified scan), TCGA case TCGA-CS-6666, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-6666-01A (Primary Tumor).

[page 1 of 4]
© 2004 Blackwell Publishing Ltd *Journal of Internal Medicine* 255: 351–358

1. Right parietal tumor: ANAPLASTIC ASTROCYTOMA, WHO GRADE iii.

3. Right parietal tumor: ANAPLASTIC ASTROCYTOMA, WHO GRADE iii. SEE MICROSCOPIC DESCRIPTION.

Ki67

Cells counted : 40,914 cells

© 2006 The Authors
Journal compilation © 2006 Blackwell Publishing Ltd

NEU-N IMMUNOHISTOCHEMICAL STAIN: NEGATIVE IN TUMOR CELLS. POSITIVE STAINING OF RESIDENT, NON-NEOPLASTIC NEURONS IN AREAS OF TUMOR INFILTRATION OF GREY MATTER.

[page 2 of 4]
Microscopic Description:

This tumor is an infiltrative glial neoplasm composed of pleomorphic astrocytes. The malignant features of this tumor are best seen in specimen #3. Tumor cells show strong positive immunohistochemical staining for GFAP. Tumor cells that are gemistocytic in appearance are present focally. Numerous mitotic figures are identified. The Ki67 proliferation index of the tumor is 16%. No ganglion cell component of the tumor is identified on chromogranin or neurofilament immunohistochemical stain. The majority of tumor cell nuclei show positive immunohistochemical staining for p53. While scattered tumor cells show immunohistochemical staining for EMA, this neoplasm does not show histologic features of an ependymoma and is best classified as Anaplastic Astrocytoma. The possibility that this neoplasm arose from a lower grade tumor cannot be excluded. Case was reviewed in conference with [REDACTED]

Case discussed with [REDACTED] An addendum with the results of Neu-N immunohistochemical stain will be issued.

Frozen Section Diagnosis:

1. Right parietal tumor: Astrocytic neoplasm, grading defer.
2. Capsule wall: Tumor present.

Frozen section diagnoses by [REDACTED]

Clinical History and Diagnosis:

Right parietal tumor

Source of Specimen:

- 1: Right parietal tumor
- 2: Capsule wall
- 3: Right parietal tumor

Gross Description:

1. Right parietal tumor: Received fresh for frozen labeled with the patient's name and #1 right parietal tumor is a 2 x 1 x 0.5 cm aggregate of tan-white soft tissue. Touch preps are prepared. Approximately 60% of the specimen is submitted for frozen section. The [REDACTED]

[page 3 of 4]
remainder of the specimen is entirely submitted in one additional cassette.

2. Capsule wall: Received fresh for frozen labeled with the patient's name and #2 capsule wall is a 0.3 x 0.2 x 0.2 cm fragment of tan tissue. Touch preps are prepared. The specimen is entirely submitted in one cassette for frozen section.

3. Right parietal tumor: Received in formalin in a specimen container labeled with the patient's name and a buccal #3 right parietal tumor" single fragment of red white soft tissue measuring 1.8 x 1.3 x 0.5 cm. The specimen is entirely submitted in one cassette.

Histology Laboratory

Part 3: Right parietal tumor

CHROMOGRANIN A

EPITHELIAL MEMBRANE Ag (EMA)

GLIAL FIBRILLARY ACIDIC PROTEIN (GFAP)

KI 67 (Aperio)

NEU - N

NEUROFILAMENT PROTEIN

P 53

SYNAPTOPHYSIN

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of [REDACTED] et.al. [REDACTED]
[REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the [REDACTED]
[REDACTED]

[page 4 of 4]
[REDACTED]

[REDACTED]

They have not been cleared by the US Food and Drug Administration.
The FDA has determined that such clearance or approval is not
necessary.

Source: NCI Genomic Data Commons file 6439d1c1-6909-4e7c-b609-3fd3f551ced8 (TCGA-CS-6666.9BC50BCF-B22B-4516-B8A9-AEC943756116.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).